Somatic mutation profile of tumor specimen TCGA-FD-A43N-01A (aliquot TCGA-FD-A43N-01A-11D-A23U-08) from TCGA case TCGA-FD-A43N, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 76.2 years (27,833 days).
Specimen TCGA-FD-A43N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b05a746-8276-4955-ac74-20f47b3309e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A43N-10A (Blood Derived Normal), aliquot TCGA-FD-A43N-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03874f9f-96f2-409d-b1d2-308a52fb0a51

The open-access MAF lists 193 somatic variants for this specimen: 140 protein-altering or splice-affecting, 51 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 51, Frame Shift Del 7, Nonsense Mutation 7, Splice Site 1, In Frame Del 1, Intron 1, Frame Shift Ins 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 19/159 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.770T>A p.L257Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934577, CD941800, CM1411657, CM941332, COSV52682484, COSV52703253, COSV52757928; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADGRA2 | c.1936C>T p.L646F | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV59443573; called by muse, mutect2, varscan2
- AHNAK | c.16343C>T p.S5448L | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758968097, COSV57213322; called by muse, mutect2, varscan2
- AHNAK | c.15910C>G p.L5304V | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.975); catalogued as COSV57213333; called by muse, mutect2, varscan2
- AHNAK | c.15408C>G p.I5136M | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV57213345; called by muse, mutect2, varscan2
- AHNAK | c.13781C>G p.S4594C | Missense Mutation (SNP) | VAF 102/260 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57213353; called by muse, mutect2, varscan2
- ANKRD17 | c.1042G>C p.D348H | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58220037; called by muse, mutect2, varscan2
- APPL1 | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV55700861, COSV55700870; called by muse, mutect2, varscan2
- ARID1A | c.4661del p.P1554Hfs*11 | Frame Shift Del (DEL) | VAF 53/137 reads (39%) | catalogued as COSV61385710; called by mutect2, pindel, varscan2
- ASCC3 | c.6003T>G p.H2001Q | Missense Mutation (SNP) | VAF 25/192 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV64975121; called by muse, mutect2, varscan2
- ATM | c.950A>G p.D317G | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53744162; called by muse, mutect2, varscan2
- ATP11A | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV52111679; called by muse, mutect2, varscan2
- BCKDHA | c.104G>T p.R35I | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54197122; called by muse, mutect2
- BHMT2 | c.830G>C p.R277T | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99669843; called by muse, mutect2, varscan2
- BRMS1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.241); catalogued as COSV60820108; called by muse, mutect2, varscan2
- BTAF1 | c.5215C>T p.R1739W | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56434067; called by muse, mutect2, varscan2
- C1orf112 | c.471G>A p.M157I | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.12); catalogued as rs367824430; called by muse, mutect2, varscan2
- C6orf136 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 36/245 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs779490606, COSV53314035; called by muse, mutect2, varscan2
- CADPS2 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs772668227, COSV57363742; called by muse, mutect2, varscan2
- CAMLG | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.206); catalogued as COSV51804732; called by muse, mutect2, varscan2
- CCM2 | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV51848357; called by muse, mutect2, varscan2
- CDC20 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 35/236 reads (15%) | catalogued as COSV100196251; called by muse, mutect2, varscan2
- CEL | c.1669G>A p.D557N (on ENST00000673714; = p.D554N on NM_001807.6) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1222858393, COSV100672138; called by muse, mutect2
- CEP126 | c.2032A>G p.T678A | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1372873010, COSV54825223; called by muse, mutect2, varscan2
- CEP68 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV53124926; called by muse, mutect2, varscan2
- CLASP2 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 61/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56277053, COSV56282419, COSV56293642; called by muse, mutect2, varscan2
- CSNK1A1 | c.92T>A p.I31N | Missense Mutation (SNP) | VAF 67/152 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV55794467; called by muse, mutect2, varscan2
- CYB5R1 | c.275G>T p.S92I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV65916978; called by muse, mutect2, varscan2
- DCPS | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 18/158 reads (11%) | catalogued as rs904572688, COSV55012549; called by mutect2, varscan2
- DDAH2 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 146/388 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV65383948; called by muse, varscan2
- DHX15 | c.2362C>G p.Q788E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61026908, COSV61028139; called by muse, mutect2
- DMD | c.4403A>C p.E1468A | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV63755112; called by muse, mutect2
- DNAH9 | c.12736G>A p.E4246K | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV52349624; called by muse, mutect2, varscan2
- DPY19L4 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 86/558 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV68962875; called by muse, mutect2, varscan2
- DSG2 | c.1476C>G p.I492M | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.201); catalogued as COSV55199164; called by muse, mutect2
- DST | c.14595G>C p.K4865N (on ENST00000361203 / NM_001374722.1; = p.K2453N on NM_015548.5) | Missense Mutation (SNP) | VAF 63/248 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.561); catalogued as COSV55014509; called by muse, mutect2, varscan2
- DUS3L | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1390053476, COSV57831947; called by muse, mutect2, varscan2
- EFHC1 | c.1034A>G p.Y345C | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.293); catalogued as COSV64136388; called by muse, mutect2, varscan2
- EIF3D | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as COSV53403626; called by muse, mutect2, varscan2
- ELF3 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs917623772, COSV62838327; called by muse, mutect2, varscan2
- ELMO1 | c.848A>C p.Q283P | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100162599; called by muse, mutect2
- EMSY | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV58260340; called by muse, mutect2
- EPHX1 | c.1249T>C p.Y417H | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1321764952, COSV55300763; called by muse, mutect2, varscan2
- EPS15L1 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs201102412, COSV50167441; called by muse, mutect2
- ESR2 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.232); catalogued as rs145661652; called by muse, mutect2, varscan2
- F8 | c.6593G>T p.G2198V | Missense Mutation (SNP) | VAF 119/155 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM080301, CM990564, COSV57705172; called by muse, mutect2, varscan2
- FAM47B | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.971); catalogued as COSV100263890, COSV61455991; called by muse, mutect2, varscan2
- FAM71A | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as COSV54235658, COSV99674787; called by muse, mutect2, varscan2
- FAM71A | c.1352G>A p.G451E | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.314); catalogued as COSV54235665; called by muse, mutect2, varscan2
- FAT4 | c.14607G>T p.M4869I | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV58685325; called by muse, mutect2
- FOXA1 | c.1416del p.*473Sfs*11 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | catalogued as COSV51644956; called by mutect2, pindel, varscan2
- FSCN3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.94); catalogued as rs201860992, COSV50000980; called by muse, mutect2, varscan2
- GALNT18 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs757382050, COSV57142838, COSV57151581; called by muse, mutect2, varscan2
- GALNT8 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs150412211; called by muse, mutect2, varscan2
- GCNT1 | c.499A>T p.M167L | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV65057745; called by muse, mutect2, varscan2
- GLB1 | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.859); catalogued as rs754538192, COSV56563660; called by muse, mutect2, varscan2
- GOLGA4 | c.2332C>A p.H778N | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV62710708; called by muse, mutect2, varscan2
- GPR158 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV66270182; called by muse, mutect2
- H1-4 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776601380, COSV56799905, COSV56803909; called by muse, mutect2
- HIF3A | c.1568G>A p.R523H (on ENST00000377670 / NM_152795.4; = p.R454H on NM_022462.4) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs747523164, COSV52198389; called by muse, mutect2, varscan2
- HIVEP3 | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as COSV99911081; called by muse, varscan2
- HOXD3 | c.653A>G p.Y218C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50880571; called by muse, mutect2
- IKZF2 | c.608del p.R203Qfs*32 | Frame Shift Del (DEL) | VAF 69/159 reads (43%) | catalogued as COSV59578675, COSV59580017; called by mutect2, pindel, varscan2
- ILF3 | c.2090G>C p.G697A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); catalogued as COSV51557576; called by muse, mutect2, varscan2
- INTS2 | c.2971C>T p.R991* | Nonsense Mutation (SNP) | VAF 42/331 reads (13%) | catalogued as rs748698616, COSV99247567; called by muse, mutect2, varscan2
- IRAK4 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV71210439; called by muse, mutect2
- ITGAL | c.258A>G p.R86= | Splice Region (SNP) | VAF 19/151 reads (13%) | catalogued as COSV63322185; called by muse, mutect2, varscan2
- ITIH3 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201794632, COSV101406916; called by muse, mutect2, varscan2
- KCNIP3 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV54666049, COSV54673710; called by muse, mutect2, varscan2
- KLHL12 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as rs1005881044, COSV66127354; called by muse, mutect2, varscan2
- KRTAP4-12 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV67457915; called by muse, mutect2
- LAMA1 | c.5056C>A p.L1686I | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.15); catalogued as COSV67536957; called by muse, mutect2, varscan2
- LARS1 | c.1873A>T p.I625F (on ENST00000394434 / NM_020117.11; = p.I598F on NM_016460.3) | Missense Mutation (SNP) | VAF 114/404 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV50976096; called by muse, mutect2, varscan2
- LIPF | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV53283912; called by muse, mutect2, varscan2
- MADD | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs776472447, COSV60620922; called by muse, mutect2, varscan2
- MARCKS | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV100892988; called by muse, mutect2, varscan2
- MFSD6L | c.1179G>A p.M393I | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.499); catalogued as COSV61003194; called by muse, mutect2, varscan2
- MINK1 | c.1924G>C p.D642H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100766926; called by muse, mutect2, varscan2
- MKI67 | c.3227T>C p.L1076P | Missense Mutation (SNP) | VAF 197/477 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs777015943, COSV64074324; called by muse, mutect2, varscan2
- MMP13 | c.1183C>G p.L395V | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV52824042; called by muse, mutect2, varscan2
- MYL10 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV56207852; called by muse, mutect2, varscan2
- MYO9B | c.4123G>C p.E1375Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.812); catalogued as COSV68279114; called by muse, mutect2, varscan2
- NACA2 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 65/160 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV71713130; called by muse, mutect2, varscan2
- NES | c.3098G>A p.G1033E | Missense Mutation (SNP) | VAF 48/435 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV63961053; called by muse, mutect2, varscan2
- NRG3 | c.1990A>T p.I664F (on ENST00000404547 / NM_001370084.1; = p.I640F on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV64561805; called by muse, mutect2
- NRSN2 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 15/269 reads (6%) | catalogued as COSV101206778; called by muse, mutect2
- OR14A16 | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.03); catalogued as COSV100713667, COSV62926650; called by muse, mutect2, varscan2
- PAPSS1 | c.1558G>T p.V520F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54489113; called by muse, mutect2, varscan2
- PCNX1 | c.2809C>A p.L937I | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as COSV53094767; called by muse, mutect2, varscan2
- PIK3C2B | c.1285T>A p.C429S | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV65803644; called by muse, mutect2, varscan2
- PIK3CG | c.375G>C p.W125C | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63248579; called by muse, mutect2, varscan2
- PKD2 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 19/332 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as rs1005107425, COSV52938282; called by muse, mutect2
- PLA2G4F | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 31/160 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs564398767, COSV51825396, COSV51826887; called by muse, mutect2, varscan2
- PPP1R3A | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV52882607; called by muse, mutect2
- PRDM9 | c.2273G>A p.R758H | Missense Mutation (SNP) | VAF 130/276 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1450853481, COSV57004243; called by muse, varscan2
- PRICKLE2 | c.2024G>A p.G675E (on ENST00000295902; = p.G619E on NM_198859.4) | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV55766339; called by muse, mutect2, varscan2
- PTGES3 | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV56273780; called by muse, mutect2, varscan2
- PTPRZ1 | c.5935G>A p.E1979K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66436520; called by muse, mutect2
- REEP6 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV52013367; called by muse, mutect2, varscan2
- RNASEL | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.763); catalogued as rs762520521, COSV62376819; called by muse, mutect2, varscan2
- RPUSD4 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53599293; called by muse, mutect2, varscan2
- RYR1 | c.13564C>G p.P4522A | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV62097244; called by muse, mutect2
- SATB1 | c.1718C>T p.A573V | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.392); catalogued as rs564141224, COSV58669497, COSV58672813; called by muse, mutect2, varscan2
- SEMG2 | c.1369C>G p.Q457E | Missense Mutation (SNP) | VAF 70/173 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV65647301, COSV65647481; called by muse, mutect2, varscan2
- SIGLEC11 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.301); catalogued as COSV70221999; called by muse, mutect2, varscan2
- SLC16A13 | c.360G>C p.L120F | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1412074117, COSV57274295; called by muse, mutect2
- SLC16A7 | c.866T>G p.M289R | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV53895029; called by muse, mutect2, varscan2
- SLC28A1 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54479099; called by muse, mutect2, varscan2
- SLC35F4 | c.1492G>A p.D498N (on ENST00000339762 / NM_001352015.2; = p.D462N on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.159); catalogued as COSV60264681; called by mutect2, varscan2
- SLIT2 | c.3464A>G p.K1155R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.02); catalogued as COSV56572539; called by muse, mutect2, varscan2
- SP8 | c.110C>T p.S37L (on ENST00000361443 / NM_198956.4; = p.S55L on NM_182700.6) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs201512381; called by muse, mutect2
- SPANXC | c.57C>A p.N19K | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143011063, COSV62841885; called by muse, mutect2, varscan2
- SPG7 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.053); catalogued as COSV51950525; called by muse, mutect2, varscan2
- SYNE3 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 28/198 reads (14%) | catalogued as COSV100515508; called by muse, mutect2, varscan2
- TLL2 | c.1824G>T p.E608D | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV63572456; called by muse, mutect2, varscan2
- TLR9 | c.2362G>C p.V788L | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as COSV62346714; called by muse, mutect2, varscan2
- TMEM175 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV53278804, COSV53281378; called by muse, varscan2
- TMEM175 | c.607_618del p.S203_F206del | In Frame Del (DEL) | VAF 8/80 reads (10%) | catalogued as COSV53278813; called by pindel, varscan2
- TMEM267 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as COSV67992683; called by muse, mutect2, varscan2
- TMPRSS15 | c.2758T>C p.Y920H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99516395; called by muse, mutect2
- TRIM60 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61970515; called by muse, mutect2, varscan2
- TSKU | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as rs200873251, COSV60751644; called by muse, mutect2, varscan2
- TTN | c.13868A>G p.D4623G (on ENST00000591111; = p.D3696G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | PolyPhen possibly damaging (0.673); catalogued as COSV60061315; called by muse, mutect2, varscan2
- TUBB | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.125); catalogued as COSV58357653; called by muse, varscan2
- UGGT1 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52133476, COSV99390074; called by muse, mutect2, varscan2
- WASF3 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as COSV58965876; called by muse, mutect2, varscan2
- ZC3H14 | c.1798C>T p.R600C | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756970794, COSV51769552; called by muse, mutect2, varscan2
- ZDBF2 | c.6227G>A p.R2076H | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs561231274, COSV65625966; called by muse, mutect2, varscan2
- ZNF385D | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV55755834; called by muse, mutect2, varscan2
- ZNF671 | c.54C>A p.C18* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | catalogued as COSV100234786; called by muse, mutect2, varscan2
- ZNFX1 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.096); catalogued as rs752089559, COSV65574094; called by muse, mutect2, varscan2
- ZRANB1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV62842483; called by muse, mutect2
- ARID1A | c.4102-1_4106del p.X1368_splice | Splice Site (DEL) | VAF 23/103 reads (22%) | called by mutect2, pindel, varscan2
- ATM | c.247T>G p.S83A | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); called by muse, mutect2
- CD63 | c.321_322insCT p.R108Lfs*5 | Frame Shift Ins (INS) | VAF 33/304 reads (11%) | called by mutect2, varscan2
- FYCO1 | c.462_463del p.Y155* | Frame Shift Del (DEL) | VAF 52/175 reads (30%) | called by pindel, varscan2
- NEMP1 | c.174_183del p.C58Wfs*27 | Frame Shift Del (DEL) | VAF 17/155 reads (11%) | called by mutect2, pindel
- PCDH1 | c.735del p.Y246Mfs*50 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- PCDHA12 | c.575del p.P192Lfs*3 | Frame Shift Del (DEL) | VAF 35/105 reads (33%) | called by mutect2, pindel, varscan2
- ACIN1 | c.1818G>A p.P606= | Silent (SNP) | VAF 104/297 reads (35%) | catalogued as rs369134837; called by muse, mutect2, varscan2
- AMPD2 | c.2088G>A p.P696= | Silent (SNP) | VAF 54/349 reads (15%) | catalogued as rs368213563, COSV56647900; called by muse, mutect2, varscan2
- ANGPTL1 | c.1296C>T p.C432= | Silent (SNP) | VAF 14/117 reads (12%) | catalogued as rs777959089, COSV52366417; called by muse, mutect2, varscan2
- ANO4 | c.2130C>T p.F710= (on ENST00000392977 / NM_001286615.2; = p.F675= on NM_178826.4) | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as rs751248544, COSV54587281; called by muse, mutect2, varscan2
- ASCC2 | c.2055G>C p.L685= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV57073755; called by muse, mutect2
- ATG2A | c.1401C>T p.F467= | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as rs776373152, COSV65966824; called by muse, mutect2, varscan2
- BRAP | c.1608C>T p.V536= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as COSV59536662; called by muse, mutect2, varscan2
- CABLES1 | c.1662C>G p.L554= (on ENST00000256925 / NM_001100619.2; = p.L289= on NM_138375.2) | Silent (SNP) | VAF 51/77 reads (66%) | catalogued as COSV56932115; called by muse, mutect2, varscan2
- CACNA1S | c.1119C>T p.G373= | Silent (SNP) | VAF 101/247 reads (41%) | catalogued as rs777414745, COSV62939468; called by muse, mutect2, varscan2
- CBX2 | c.957G>A p.Q319= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs781966024, COSV53969052; called by muse, mutect2, varscan2
- CCNP | c.195G>T p.L65= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV55687663; called by muse, mutect2, varscan2
- CSHL1 | c.105T>C p.L35= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs1167344948, COSV51988105; called by muse, mutect2
- DECR1 | c.31C>T p.L11= | Silent (SNP) | VAF 33/97 reads (34%) | catalogued as rs1187455871, COSV55168572; called by muse, mutect2, varscan2
- DNAH6 | c.2457G>C p.V819= | Silent (SNP) | VAF 47/134 reads (35%) | catalogued as COSV52861075; called by muse, mutect2, varscan2
- DSP | c.3768C>G p.L1256= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as COSV65792718; called by muse, mutect2, varscan2
- EFR3A | c.2118G>A p.Q706= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99602263, COSV99602520; called by muse, mutect2
- FAM227B | c.1017C>T p.I339= | Silent (SNP) | VAF 76/206 reads (37%) | catalogued as rs145082626, COSV54810383; called by muse, mutect2, varscan2
- FMN2 | c.2979C>T p.P993= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as rs751443109, COSV100141933; called by muse, mutect2, varscan2
- GIMAP8 | c.42C>G p.L14= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as COSV56231466; called by muse, mutect2, varscan2
- GPER1 | c.120C>T p.T40= | Silent (SNP) | VAF 48/165 reads (29%) | catalogued as rs140084051; called by muse, mutect2, varscan2
- H2BC1 | c.174G>A p.S58= | Silent (SNP) | VAF 45/329 reads (14%) | catalogued as rs376615409; called by muse, mutect2, varscan2
- H2BC18 | c.84G>A p.K28= | Silent (SNP) | VAF 151/418 reads (36%) | catalogued as rs1553754615, COSV58944236, COSV58944337; called by muse, mutect2, varscan2
- HAO2 | c.411G>A p.L137= | Silent (SNP) | VAF 93/220 reads (42%) | catalogued as COSV58039523; called by muse, mutect2, varscan2
- IGSF9B | c.3141C>T p.F1047= | Silent (SNP) | VAF 75/122 reads (61%) | catalogued as rs757925560, COSV58064152, COSV58067565; called by muse, mutect2, varscan2
- ITGAM | c.1383C>G p.L461= | Silent (SNP) | VAF 53/263 reads (20%) | catalogued as COSV54937115; called by muse, mutect2, varscan2
- LAMP1 | c.1056C>G p.V352= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV58150086; called by muse, mutect2, varscan2
- MAPK7 | c.735C>G p.L245= | Silent (SNP) | VAF 50/66 reads (76%) | catalogued as COSV55190465; called by muse, mutect2, varscan2
- MBLAC2 | c.567C>T p.D189= | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as rs185321716, COSV57302190; called by muse, mutect2, varscan2
- MED13L | c.4143C>T p.P1381= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV56120058; called by muse, mutect2, varscan2
- MMP10 | c.1011A>G p.S337= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs1330913069, COSV54246267; called by muse, mutect2
- NDC1 | c.508C>T p.L170= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as COSV52335190; called by muse, mutect2, varscan2
- NKPD1 | c.2070C>G p.L690= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV58728892; called by muse, varscan2
- NLRP5 | c.3531C>G p.L1177= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as rs764078123, COSV66764533; called by muse, mutect2, varscan2
- OXT | c.273G>A p.A91= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV54131963; called by muse, mutect2, varscan2
- PANK1 | c.1629G>T p.V543= (on ENST00000307534 / NM_148977.2; = p.V259= on NM_138316.4) | Silent (SNP) | VAF 13/180 reads (7%) | catalogued as COSV56808100; called by muse, mutect2
- PCDH8 | c.1050C>T p.N350= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1246198933, COSV58812667; called by muse, mutect2
- PCDHA4 | c.159A>G p.G53= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs373851381; called by muse, mutect2
- RNF17 | c.1137G>A p.Q379= | Silent (SNP) | VAF 116/320 reads (36%) | catalogued as COSV55040520; called by muse, mutect2, varscan2
- RYR3 | c.5544C>T p.L1848= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1022624253, COSV101211777; called by muse, mutect2, varscan2
- SCAPER | c.552A>G p.P184= | Silent (SNP) | VAF 50/97 reads (52%) | catalogued as COSV57736271; called by muse, mutect2, varscan2
- SDK1 | c.948A>T p.I316= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV67368777; called by muse, mutect2, varscan2
- SHBG | c.528C>G p.L176= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV52646791; called by muse, mutect2, varscan2
- SPEN | c.2763G>A p.Q921= | Silent (SNP) | VAF 34/513 reads (7%) | catalogued as COSV65361799; called by muse, mutect2
- SPTAN1 | c.759G>T p.G253= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV63987118; called by muse, mutect2, varscan2
- SUFU | c.900C>T p.L300= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV64014824; called by muse, mutect2, varscan2
- SVEP1 | c.5544T>A p.G1848= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV52839246; called by muse, mutect2, varscan2
- TTN | c.55623G>T p.L18541= (on ENST00000591111; = p.L11117= on NM_003319.4) | Silent (SNP) | VAF 67/335 reads (20%) | catalogued as COSV60061267; called by muse, mutect2, varscan2
- TUBGCP4 | c.957C>G p.L319= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as COSV53019093; called by muse, mutect2, varscan2
- UBE3C | c.2253G>T p.R751= | Silent (SNP) | VAF 86/238 reads (36%) | catalogued as COSV61953189, COSV61954993; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2400G>C p.S800= | Silent (SNP) | VAF 26/196 reads (13%) | catalogued as COSV54435191; called by muse, mutect2, varscan2
- ZAN | c.387C>T p.G129= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1309991980, COSV61806563, COSV61809101; called by muse, mutect2
- FAM27E5 | n.248C>T | RNA (SNP) | VAF 86/186 reads (46%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31011C>T | Intron (SNP) | VAF 12/76 reads (16%) | catalogued as rs773794462, COSV55159461; called by muse, mutect2, varscan2
